Somatic mutation profile of tumor specimen TCGA-KN-8431-01A (aliquot TCGA-KN-8431-01A-11D-2310-10) from TCGA case TCGA-KN-8431, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 35.7 years (13,043 days).
Specimen TCGA-KN-8431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc0b0a6f-16eb-44b5-992c-d71ca60355b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8431-11A (Solid Tissue Normal), aliquot TCGA-KN-8431-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/959b30e1-0c29-425a-add8-0c58993d66cc

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Silent 2, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1035298569; called by muse, varscan2
- HADHB | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); catalogued as rs1347850489, COSV100502011; called by muse, mutect2, varscan2
- KIF2A | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs750318761; called by muse, mutect2, varscan2
- SOS2 | c.1638T>A p.S546R | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.498); catalogued as COSV99366121; called by muse, mutect2
- WAS | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64997820; called by muse, mutect2
- NDUFS1 | c.896G>C p.R299P | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPY2R | c.944T>A p.M315K | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC3L4 | c.2152C>T p.L718= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1299135030; called by muse, mutect2
- RINT1 | c.354T>C p.N118= | Silent (SNP) | VAF 64/185 reads (35%) | called by muse, mutect2, varscan2
- DST | c.4297-1520G>A | Intron (SNP) | VAF 29/41 reads (71%) | catalogued as rs1329545752; called by muse, mutect2, varscan2
- S1PR3 | c.*1016C>A | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100822542; called by muse, mutect2
- STK11IP | c.2869+47C>T | Intron (SNP) | VAF 42/74 reads (57%) | catalogued as rs1245286248; called by muse, mutect2, varscan2
- ZNF436 | c.-230dup | 5'UTR (INS) | VAF 27/52 reads (52%) | called by mutect2, pindel, varscan2
